Gene-level copy-number profile of specimen HCM-CSHL-0141-C18-85A from HCMI case HCM-CSHL-0141-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 67.2 years (24,563 days).
Specimen HCM-CSHL-0141-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 76088c3c-ec94-4507-9795-2fcb5b3b7c96.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0141-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/ff29d53c-1554-4b3a-b255-287698cebad1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 1: 629; copy number 2: 7,368; copy number 3: 34,751; copy number 4: 13,558; copy number 5: 1,817; copy number 6: 132; copy number 7: 72; copy number 11: 21; copy number 13: 11; copy number 15: 5; copy number 17: 26; copy number 19: 2; copy number 34: 8.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 145 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:27,066,707–27,549,913, 13 genes, copy number 13–19: C16orf82, AC092725.1, EEF1A1P38, LINC02129, KDM8, AC109449.1, NSMCE1, NSMCE1-DT, AC106739.1, IL4R, IL21R, IL21R-AS1, GTF3C1.
- chr16:50,065,970–50,107,272, 1 gene, copy number 11 (within-gene range 5–11): HEATR3.
- chr16:50,098,264–52,677,747, 59 genes, copy number 11–34: RNY4P3, AC007610.2, AC007610.5, RPL10P14, SNORA70, TENT4B, ADCY7, MIR6771, BRD7, AC007493.2, LINC02178, AC007493.1, NKD1, AC007608.2, AC007608.4, AC007608.1, AC007608.3, SNX20, NOD2, AC007728.3, AC007728.2, CYLD, MIR3181, AC007728.1, LINC02168, LINC02128, AC025810.1, RNA5SP426, LINC02127, AC027688.1, AC027688.2, SOD1P2, SALL1, AC009166.1, AC087564.1, AC009166.2, AC137494.1, AC137527.1, UNGP1, AC007344.1, HNRNPA1P48, RN7SKP142, LINC01571, C16orf97, AC009039.1, AC009039.2, LINC00919, LINC02180, AC007333.2, AC007333.1, CASC22, TOX3, AC007490.1, CASC16, AC026462.5, AC026462.3, AC026462.2, AC026462.4, AC026462.1.
- chr17:21,428,263–21,574,517, 1 gene, copy number 7 (within-gene range 2–7): LINC02693.
- chr17:21,532,974–22,070,538, 11 genes, copy number 7: AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1, AC233702.4, AC233702.9, KCNJ18, ABBA01006766.1, NCOR1P2.
- chr17:64,477,785–67,056,797, 60 genes, copy number 7: POLG2, ATP5MFP4, DDX5, MIR3064, MIR5047, CEP95, SMURF2, AC009994.1, MICOS10P2, ARHGAP27P1-BPTFP1-KPNA2P3, KPNA2P3, AC132812.1, BPTFP1, AC103810.3, PLEKHM1P1, MIR6080, MIR4315-2, RNU7-115P, AC103810.9, LRRC37A3, RN7SL404P, AC103810.6, AC103810.7, AC103810.2, AC103810.5, RDM1P4, AC103810.1, AC103810.4, AC037487.4, AC103810.8, AC037487.1, AC037487.3, SLC16A6P1, AMZ2P1, GNA13, AC037487.2, RGS9, AC060771.1, LINC02563, AXIN2, AC004805.1, CEP112, AC004805.3, AC004805.2, PSMD7P1, APOH, RNA5SP444, PRKCA, RN7SL735P, PRKCA-AS1, RNU6-928P, RNA5SP445, AC006947.1, MIR634, CACNG5, RNA5SP446, CACNG4, AC005544.1, AC005544.2, CACNG1.

Autosomal genes at a single copy (total copy number 1): 629. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
